Gene-level copy-number profile of specimen HCM-CSHL-0320-C02-85A from HCMI case HCM-CSHL-0320-C02, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX.
Specimen HCM-CSHL-0320-C02-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 839272d5-b4c8-49b6-accf-d3c690b2b855.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0320-C02-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/c6661198-efef-418c-a43f-8f4a793d5d15

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,222; copy number 2: 11,425; copy number 3: 16,308; copy number 4: 24,745; copy number 5: 2,151; copy number 6: 359; copy number 7: 2,286; copy number 8: 370; copy number 9: 21; copy number 10: 12; copy number 11: 2; copy number 12: 1; copy number 25: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 40 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:29,351,292–30,250,092, 27 genes, copy number 9–10: AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1.
- chr8:30,995,802–31,176,138, 3 genes, copy number 9 (within-gene range 8–9): PURG, WRN, SUMO2P16.
- chr8:31,275,542–31,390,805, 2 genes, copy number 9: AC068672.2, AC068672.3.
- chr8:31,598,099–31,598,204, 1 gene, copy number 9: RNA5SP261.
- chr9:61,581,813–61,789,426, 6 genes, copy number 11–25: AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P.
- chr9:63,581,254–63,581,834, 1 gene, copy number 12: AL591438.1.

Autosomal genes at a single copy (total copy number 1): 352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
